Somatic mutation profile of tumor specimen TCGA-5R-AA1D-01A (aliquot TCGA-5R-AA1D-01A-11D-A382-10) from TCGA case TCGA-5R-AA1D, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 17.9 years (6,545 days).
Specimen TCGA-5R-AA1D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36ce8dce-395e-4785-8619-b821f225b88c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5R-AA1D-10A (Blood Derived Normal), aliquot TCGA-5R-AA1D-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b20f4f46-5685-4680-9805-748c0148c43a

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOF | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100028844; called by muse, mutect2
- CDH9 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV50384520, COSV99144061; called by muse, mutect2, varscan2
- FAM3A | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100453607; called by muse, mutect2, varscan2
- FAM47B | c.1637T>A p.I546K | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV100264293; called by muse, mutect2
- HDAC4 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs115358346, COSV61864881; called by muse, mutect2, varscan2
- HIRIP3 | c.20T>C p.M7T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99663006; called by muse, mutect2, varscan2
- OTUB1 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | catalogued as COSV56839412; called by muse, mutect2, varscan2
- PON2 | c.462T>G p.H154Q | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99749654; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV99541573; called by muse, mutect2, varscan2
- WNT7A | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99541260; called by muse, mutect2, varscan2
- ADAMTS20 | c.5706T>C p.T1902= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV101239211; called by muse, mutect2, varscan2
- KLHL21 | c.273G>A p.L91= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs570481805, COSV100887229; called by mutect2, varscan2
- NLRP6 | c.1458G>T p.P486= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100381004; called by muse, mutect2, varscan2
- XPO7 | c.1062G>A p.E354= | Silent (SNP) | VAF 4/96 reads (4%) | catalogued as COSV99381167; called by muse, mutect2
- HHIPL1 | c.1730+618G>A | Intron (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100415106; called by muse, mutect2, varscan2
